Somatic mutation profile of tumor specimen 0DCER4 from CCDI case PBBMAW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.5 years (5,646 days).
Specimen 0DCER4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 421600cf-ebf6-4d7d-9d4a-ef9cdc8b87b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCEQW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ea644c5-7bf9-4c32-945d-ad613cea3957

The open-access MAF lists 29 somatic variants for this specimen: 22 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 3, RNA 3, Splice Site 2, Frame Shift Del 1, 3'UTR 1, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH3 | c.307C>T p.R103* | Nonsense Mutation (SNP) | VAF 60/1080 reads (6%) | catalogued as rs1157108621; ClinVar: pathogenic; called by muse, mutect2
- CTNNB1 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 404/987 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic /  other; called by muse, mutect2, varscan2
- PTCH1 | c.1485del p.F495Lfs*47 | Frame Shift Del (DEL) | VAF 383/967 reads (40%) | catalogued as rs1554698531; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCD1 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 159/393 reads (40%) | SIFT tolerated (0.61); PolyPhen benign (0.02); catalogued as rs1557052298, CD994514; called by muse, mutect2, varscan2
- CALHM2 | c.425C>T p.T142M | Missense Mutation (SNP) | VAF 514/1117 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs755514193; called by muse, mutect2, varscan2
- CD80 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 680/1350 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV51801944; called by muse, mutect2, varscan2
- EZH2 | c.892C>T p.P298S (on ENST00000460911 / NM_001203247.2; = p.R298C on NM_004456.5) | Missense Mutation (SNP) | VAF 471/1238 reads (38%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.608); catalogued as COSV99053008; called by muse, mutect2, varscan2
- LPGAT1 | c.916C>T p.R306W | Missense Mutation (SNP) | VAF 192/968 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65352083; called by muse, mutect2, varscan2
- NOTCH1 | c.362C>T p.T121M | Missense Mutation (SNP) | VAF 336/709 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as rs529738206; called by muse, mutect2, varscan2
- SLC39A7 | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 236/257 reads (92%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1202409452, COSV63002249; called by muse, mutect2, varscan2
- TTC8 | c.114+1G>T p.X38_splice | Splice Site (SNP) | VAF 67/438 reads (15%) | catalogued as COSV99075865; called by muse, mutect2, varscan2
- AC104452.1 | c.827A>T p.D276V | Missense Mutation (SNP) | VAF 48/990 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.025); called by muse, mutect2
- AIFM1 | c.745T>C p.S249P | Missense Mutation (SNP) | VAF 58/1314 reads (4%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.503); called by muse, mutect2
- BARX2 | c.836G>A p.S279N | Missense Mutation (SNP) | VAF 256/611 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- CCDC177 | c.815G>A p.R272K | Missense Mutation (SNP) | VAF 142/359 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- DDX3X | c.1501_1503del p.A501del (on ENST00000399959; = p.A502del on NM_001356.5) | In Frame Del (DEL) | VAF 264/780 reads (34%) | called by pindel, varscan2
- DPP7 | c.565G>T p.V189F | Missense Mutation (SNP) | VAF 290/730 reads (40%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.946); called by mutect2, varscan2
- HECW2 | c.4146+1G>T p.X1382_splice | Splice Site (SNP) | VAF 284/598 reads (47%) | called by muse, mutect2, varscan2
- MAGEB6B | c.196G>A p.G66R | Missense Mutation (SNP) | VAF 366/970 reads (38%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.792); called by muse, varscan2
- NCOR2 | c.3038A>T p.Q1013L | Missense Mutation (SNP) | VAF 299/612 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- UPRT | c.195C>A p.D65E | Missense Mutation (SNP) | VAF 476/1131 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- USP11 | c.1394C>T p.T465M (on ENST00000218348; = p.T422M on NM_001371072.1) | Missense Mutation (SNP) | VAF 279/755 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHB4 | c.1671G>A p.S557= | Silent (SNP) | VAF 82/230 reads (36%) | catalogued as COSV52027112; called by muse, varscan2
- RBL1 | c.1308G>A p.E436= | Silent (SNP) | VAF 239/1117 reads (21%) | catalogued as COSV60333714; called by muse, mutect2, varscan2
- RGL1 | c.1314C>T p.I438= (on ENST00000360851 / NM_001297672.2; = p.I473= on NM_015149.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 175/517 reads (34%) | catalogued as rs770302492; called by muse, mutect2, varscan2
- MMP1 | c.*93T>C | 3'UTR (SNP) | VAF 101/225 reads (45%) | called by muse, mutect2, varscan2
- MUC19 | n.12065C>G | RNA (SNP) | VAF 246/1130 reads (22%) | called by muse, mutect2, varscan2
- RPL6P21 | n.115C>T | RNA (SNP) | VAF 97/207 reads (47%) | catalogued as rs995816695; called by muse, mutect2, varscan2
- SH2D6 | n.210del | RNA (DEL) | VAF 7/91 reads (8%) | called by mutect2, pindel
